Somatic mutation profile of tumor specimen 0DQQBT from CCDI case PBCFEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.1 years (1,142 days).
Specimen 0DQQBT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8a80966-2449-474f-9bbb-bddb1bd9f7c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09a55bed-0e2a-495f-b5fb-d92242eb4623

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 90/327 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1C | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59722382; called by muse, mutect2, varscan2
- FAM47B | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 204/455 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100264670; called by muse, mutect2, varscan2
- FBRSL1 | c.3037G>A p.G1013R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1260284745; called by muse, mutect2
- HELZ2 | c.7670G>A p.R2557H (on ENST00000467148 / NM_001037335.2; = p.R1988H on NM_033405.3) | Missense Mutation (SNP) | VAF 44/696 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs770518386, COSV64443620; called by muse, mutect2
- MAGEC1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 184/654 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs776145948, COSV99596235; called by muse, mutect2, varscan2
- TLE6 | c.656C>T p.P219L (on ENST00000246112 / NM_001143986.2; = p.P96L on NM_024760.3) | Missense Mutation (SNP) | VAF 130/751 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs778120083; called by muse, mutect2, varscan2
- NXF1 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 205/505 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- PTCH1 | c.716_731del p.A239Gfs*6 | Frame Shift Del (DEL) | VAF 180/216 reads (83%) | called by mutect2, pindel, varscan2
- PXYLP1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 197/492 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC1A6 | c.1069G>C p.V357L | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPS1 | c.478G>T p.A160S (on ENST00000220888 / NM_001330599.2; = p.A173S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/402 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS37B | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 41/503 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- MYCN | c.132C>T p.P44= | Silent (SNP) | VAF 91/331 reads (27%) | catalogued as COSV99808419; called by muse, mutect2, varscan2
- FKBP10 | chr17:41812997 G>T | 5'Flank (SNP) | VAF 62/177 reads (35%) | called by muse, mutect2, varscan2
